Surgical pathology report (de-identified scan), TCGA case TCGA-44-3398, project TCGA-LUAD (Lung Adenocarcinoma), tissue source site Christiana Healthcare, specimen TCGA-44-3398-01A (Primary Tumor).

[page 1 of 3]
SPECIMEN

- A. Lymph node level 10
- B. Right lower lobe
- C. Lymph node level 7
- D. Lymph node level 3
- E. Lymph node R4

CLINICAL NOTES

--

GROSS DESCRIPTION

A. Received in formalin, labeled "lymph node level 10" and consists of multiple pieces of black soft tissue measuring 2 cm in greatest aggregate dimension. AS-1.

B. The specimen is received unfixed labeled "right lower lobe" and consists of a lobe weighing 266 grams and measuring 16 x 12 x 7 cm. There is a subtotal probable mass measuring 2.5 x 1.5 x 2 cm. There is a puckered appearance over the mass. Portions of the specimen are taken for research purposes. Additional sections after fixation. There is a stapled margin on one side of the specimen measuring 5 cm in length and there is a stapled bronchial margin as well. [REDACTED]

C. Received in formalin, labeled "lymph node level 7" and consists of multiple pieces of black soft tissue measuring 2 cm in greatest aggregate dimension. AS-1.

D. Received in formalin, labeled "lymph node level 3" and consists of a piece of white and black and yellow soft tissue measuring 2.5 x 1.5 x 0.3 cm. AS-1.

E. Received in formalin, labeled "lymph node - R4" and consists of multiple pieces of yellow and black soft tissue measuring 3 x 3 x 0.5 cm in aggregate. AS-2.

[REDACTED]

[page 2 of 3]
MICROSCOPIC DESCRIPTION

- A. There is no evidence of malignancy in any of ten lymph node pieces.
- B. Tumor type: Non-small cell carcinoma
Tumor grade: 3 out of 3
Mitotic Index: 1 mitoses/10 HPFs (1 HPF = 0.19 sq mm)
Tumor size: 2.5 cm
Bronchial resection margin: Negative for malignancy
Pulmonary margin of resection: Negative for malignancy
Pleura: Negative for malignancy
Vascular invasion: Absent
Attached lymph nodes: There is no evidence of malignancy in
any of 3 lymph nodes
pTNM Stage: T1b N0
Non-tumorous lung: Mild to moderate emphysema
- C. There's no evidence of malignancy in any of multiple lymph node pieces. Approximately 12 pieces are present.
- D. A single lymph node is negative for malignancy.
- E. There is no evidence of malignancy in any of 16 lymph node pieces.

DIAGNOSIS

- A. Lymph node, level 10, biopsy: There is no evidence of malignancy in any of ten lymph node pieces.
- B. Lung, right lower lobe, resection: Poorly differentiated non-small cell carcinoma

[page 3 of 3]
DIAGNOSIS

C.Lymph node, level 7, biopsy: There is no evidence of malignancy
in any of 12 lymph nodes pieces.

D. Lymph node, level 3, biopsy: A single lymph node is negative for malignancy.

E. Lymph node, R4, biopsy: There's no evidence of malignancy in any of 16 lymph nodes pieces.

--- End Of Report ---

Source: NCI Genomic Data Commons file 0efba296-2145-4f93-ace5-158574c39122 (TCGA-44-3398.7DC9C668-3304-47D8-9C33-5B72352672DB.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).